Surgical pathology report (de-identified scan), TCGA case TCGA-CL-5917, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Harvard, specimen TCGA-CL-5917-01A (Primary Tumor).

[page 1 of 3]
Resident: [REDACTED]
Pathologist: [REDACTED]

PATHOLOGIC DIAGNOSIS:

- A. SPECIMEN LABELED "RIGHT LIVER LOBE" (INCLUDING FSA):
Liver with fibrotic nodule with cystic change suggestive of sclerosed hemangioma.
There is no evidence of malignancy.
- B. SPECIMEN LABELED "OMENTAL BX" (INCLUDING FSB):
Fibroadipose tissue with no tumor present.
- C. SPECIMEN LABELED "SIGMOID AND RECTUM" (16.5 cm):
ADENOCARCINOMA, MODERATELY DIFFERENTIATED (4.5 cm in greatest dimension).
Tumor is located at the rectosigmoid junction, forms a fungating mass, is ulcerative and has an infiltrating border.
Tumor invades through muscularis propria into pericolic adipose tissue.
Proximal, distal, and radial resection margins are negative for tumor.
Invasive tumor is 9.5 cm from proximal resection margin, 6.5 cm from distal resection margin, and 3.0 cm from radial resection margin.
Intramural and extramural lymphovascular invasion is identified.
Extramural venous invasion is identified.
Perineural invasion is identified.
Peritumoral lymphoid response (involving Crohn's-like infiltrate) is not present.
Residual adenoma is absent.
Other polyps identified include: 1 adenoma (1.5 cm).
REGIONAL LYMPH NODES (POSITIVE/TOTAL) 4/11
AJCC Classification (6th Edition): T3 N2 MX
- D. SPECIMEN LABELED "DISTAL DONUT":
Portion of colon with no significant pathologic change.
- E. SPECIMEN LABELED "PROXIMAL DONUT":
Portion of colon with no significant pathologic change.

CLINICAL DATA:

History: Rectal Ca - on sigmoidoscopy. Liver cysts (multiple on CT) ? mets.
Operation: Low anterior resection.
Operative Findings: None given.
Clinical Diagnosis: Not provided.

TISSUE SUBMITTED:

- A. Right liver lobe [REDACTED]
B. Omental bx [REDACTED]
C. Sigmoid + rectum
D. Distal donut
E. Proximal donut

O.R. CONSULTATION:

SPECIMEN LABELED "#1. RIGHT LOBE LIVER" (FSA):
Liver with collapsed fibrous wall cyst with dystrophic calcifications.
Negative for carcinoma.

[page 2 of 3]
SPECIMEN LABELED "#2. OMENTAL BX" (FSB):

Fat necrosis.

Negative for carcinoma.

SPECIMEN LABELED "#3. RECTUM AND SIGMOID" (GROSS ONLY):

Tumor is 4.8 cm in greatest dimension and is located 9.5 cm from the stapled margin and 6.5 cm from the open margin.

The senior physician certifies that he/she personally conducted a gross and/or microscopic examination of the described specimen(s) and rendered or confirmed the rapid diagnos(es) related thereto.

GROSS DESCRIPTION:

The specimen is received fresh, in five parts, each labeled with the patients name and unit number.

Part A, labeled "Right liver lobe", consists of one fragment of liver (1.2 x 1.0 x 0.6 cm) containing a white mass (0.7 x 0.5 x 0.5 cm). A representative section is submitted as FSA.

Micro A1: FSA remnant, 1 frag,

Micro A2: Non-frozen tissue, 1 frag,

Part B, labeled "Omental biopsy", consists of one fragment of adipose tissue (0.4 x 0.3 x 0.1 cm) with no masses or lesions. The specimen is entirely submitted as FSB.

Micro B1: FSB remnant, 1 frag,

Part C, labeled "Sigmoid + rectum", consists of segment colon (16.5 cm in length x 4.5 cm in diameter) with attached pericolonic fat (3.5 cm in thickness). The proximal stapled resection margin (4.5 cm) is inked blue and the distal stapled resection margin (3.2 cm) is inked green. A fungating ulcerative mass with rolled edges (4.5 x 2.5 x 0.6 cm) is present 9.5 cm from the proximal stapled resection margin and 6.5 cm from the distal stapled resection margin. Representative sections of tumor and normal tissue are submitted to the tissue bank. The tumor is located 3.0 cm from the radial margin (inked orange). A single firm white nodule consistent with a replaced lymph node is present abutting the radial margin (0.9 cm in greatest dimension). The tumor focally invades into the underlying adipose tissue. In addition a pedunculated polyp (1.5 x 0.8 x 0.8 cm) is present 3.1 cm from the proximal stapled resection margin.

Micro C1-C2: 10 candidate lymph nodes, 5 frags each,

Micro C3: 1 lymph node trisected (close to margin), 3 frags,

Micro C4: 1 lymph node bisected, 2 frags,

Micro C5: 5 candidate lymph nodes, 5 frag

Micro C6: margins, 2 frags,

Micro C7-C9: tumor and potential invasion into adipose tissue, 1 frag,

Micro C10: tumoral to normal mucosa, 1 frag,

Micro C11: polyp, 1 frag,

Part D, labeled "Distal donut", consists of a fragment of colon (2.0 x 1.5 x 0.7 cm), with a centrally stapled hole.

Micro D1: distal donut, 1 frag,

Part E, labeled "Proximal donut", consists of anvil shaped donut maker with an attached colon ring (2.0 x 1.5 x 0.5 cm).

Micro E1: distal donut, 1 frag,

[page 3 of 3]
By his/her signature below, the senior physician certifies that he/she personally conducted a microscopic examination ("gross only" exam if so stated) of the described specimen(s) and rendered or confirmed the diagnosis(es) related thereto.

Source: NCI Genomic Data Commons file 1aa3cc6c-fe07-4b4c-b9a2-33a2b5f2e347 (TCGA-CL-5917.0F11A7EB-FA39-4CC4-887B-96FB59A98A1B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).